Somatic mutation profile of tumor specimen MMRF_2191_1_BM_CD138pos (aliquot MMRF_2191_1_BM_CD138pos_T1_KHS5U_L09504) from MMRF case MMRF_2191, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 59.1 years (21,569 days).
Specimen MMRF_2191_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 50f6391b-b6f6-4757-8770-8d6a1a9f0c2b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2191_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2191_1_PB_Whole_C2_KHS5U_L09503; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/26dc2a13-8c74-47e9-8540-d94cbd5b36e8

The open-access MAF lists 58 somatic variants for this specimen: 29 protein-altering or splice-affecting, 8 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, 3'UTR 14, Silent 8, Intron 4, Nonsense Mutation 4, 5'UTR 2, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CADPS2 | c.2179G>A p.G727S | Missense Mutation (SNP) | VAF 51/76 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757772410; called by muse, mutect2, varscan2
- DOCK3 | c.2554C>T p.R852C | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs992497683, COSV99815853; called by muse, mutect2, varscan2
- EPB42 | c.776G>A p.R259Q (on ENST00000441366 / NM_001114134.2; = p.R289Q on NM_000119.3) | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs376679347; called by muse, mutect2, varscan2
- IGHV2-70 | c.143T>G p.L48R | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as rs368172828; called by muse, varscan2
- IGLV3-19 | c.155G>C p.S52T | Missense Mutation (SNP) | VAF 26/26 reads (100%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs76281239; called by muse, varscan2
- IGLV3-19 | c.321C>G p.N107K | Missense Mutation (SNP) | VAF 34/36 reads (94%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as rs560124699; called by muse, mutect2
- IGLV6-57 | c.263G>A p.S88N | Missense Mutation (SNP) | VAF 88/167 reads (53%) | SIFT tolerated, low confidence (0.45); PolyPhen possibly damaging (0.696); catalogued as rs766366922; called by muse, varscan2
- NECAB2 | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 43/49 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs150219439; called by muse, mutect2, varscan2
- PCDHA3 | c.1367C>T p.S456L | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as rs868939985, COSV63540166; called by muse, mutect2, varscan2
- PDCD1LG2 | c.197C>G p.T66R | Missense Mutation (SNP) | VAF 102/172 reads (59%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.931); catalogued as COSV67205461; called by muse, mutect2, varscan2
- PNMA2 | c.1054C>T p.R352* | Nonsense Mutation (SNP) | VAF 89/189 reads (47%) | catalogued as COSV101580614; called by muse, mutect2, varscan2
- TTLL5 | c.1451G>A p.R484H | Missense Mutation (SNP) | VAF 50/52 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs746377581, COSV54041207; called by muse, mutect2, varscan2
- ABCB11 | c.3249T>A p.C1083* | Nonsense Mutation (SNP) | VAF 26/43 reads (60%) | called by muse, mutect2, varscan2
- ACD | c.357+7C>T | Splice Region (SNP) | VAF 57/64 reads (89%) | called by muse, mutect2, varscan2
- ARAP3 | c.4505G>A p.G1502D | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- C3 | c.1322T>A p.M441K | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- GMIP | c.1907C>T p.P636L | Missense Mutation (SNP) | VAF 76/217 reads (35%) | SIFT tolerated (0.92); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- HK1 | c.2260G>A p.V754I | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- IGHV1-69D | c.298A>T p.M100L | Missense Mutation (SNP) | VAF 61/268 reads (23%) | SIFT tolerated (0.6); PolyPhen benign (0.026); called by muse, varscan2
- IGHV1-69D | c.237C>G p.Y79* | Nonsense Mutation (SNP) | VAF 58/272 reads (21%) | called by muse, varscan2
- IGHV2-70D | c.202T>A p.W68R | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- IGHV3-64 | c.158C>A p.A53D | Missense Mutation (SNP) | VAF 54/115 reads (47%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LOXHD1 | c.3646A>T p.T1216S | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- LRP1B | c.1652C>T p.P551L | Missense Mutation (SNP) | VAF 140/246 reads (57%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MGAT5B | c.1488C>A p.Y496* (on ENST00000569840 / NM_001199172.2; = p.Y494* on NM_144677.3) | Nonsense Mutation (SNP) | VAF 44/100 reads (44%) | called by muse, mutect2, varscan2
- OMP | c.226G>A p.G76S | Missense Mutation (SNP) | VAF 82/165 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRDM10 | c.1045C>G p.R349G | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2
- WDR6 | c.754G>C p.G252R | Missense Mutation (SNP) | VAF 74/225 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- ZNF704 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 6/140 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2
- ARHGAP5 | c.2265A>G p.E755= | Silent (SNP) | VAF 40/106 reads (38%) | called by muse, mutect2, varscan2
- CNTNAP1 | c.633T>G p.L211= | Silent (SNP) | VAF 29/81 reads (36%) | called by muse, mutect2, varscan2
- IGHV2-70D | c.339G>T p.T113= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as rs1441146570; called by muse, varscan2
- MICA | c.900G>T p.V300= | Silent (SNP) | VAF 31/72 reads (43%) | catalogued as rs763446819; called by muse, mutect2, varscan2
- PCDHGA1 | c.1515C>T p.L505= | Silent (SNP) | VAF 9/189 reads (5%) | called by muse, mutect2
- POLB | c.682C>T p.L228= | Silent (SNP) | VAF 49/91 reads (54%) | called by muse, mutect2, varscan2
- SLC17A4 | c.1476G>A p.Q492= | Silent (SNP) | VAF 145/272 reads (53%) | called by muse, mutect2, varscan2
- SYNRG | c.3009G>A p.T1003= | Silent (SNP) | VAF 3/43 reads (7%) | catalogued as rs375612874; called by muse, mutect2
- AC244197.3 | c.*4896A>G | 3'UTR (SNP) | VAF 96/99 reads (97%) | catalogued as rs888558348; called by muse, mutect2, varscan2
- AEN | c.*1357del | 3'UTR (DEL) | VAF 8/50 reads (16%) | called by mutect2, varscan2
- ATG7 | c.*2334C>A | 3'UTR (SNP) | VAF 11/77 reads (14%) | called by muse, mutect2, varscan2
- C12orf57 | chr12:6944009 C>G | 5'Flank (SNP) | VAF 35/139 reads (25%) | catalogued as rs782255944; called by muse, mutect2, varscan2
- C22orf23 | c.*433T>C | 3'UTR (SNP) | VAF 34/71 reads (48%) | called by muse, mutect2, varscan2
- DCC | c.4254+33A>C | Intron (SNP) | VAF 24/53 reads (45%) | called by muse, mutect2, varscan2
- FLT1 | c.*542C>T | 3'UTR (SNP) | VAF 63/71 reads (89%) | catalogued as rs929896161; called by muse, mutect2, varscan2
- IAPP | c.*757G>C | 3'UTR (SNP) | VAF 27/112 reads (24%) | catalogued as rs1478662198; called by muse, mutect2, varscan2
- LY6D | c.*173del | 3'UTR (DEL) | VAF 40/76 reads (53%) | called by mutect2, varscan2
- LY6D | c.*172del | 3'UTR (DEL) | VAF 43/114 reads (38%) | called by mutect2*, pindel, varscan2*
- MAP6 | c.1316+642G>A | Intron (SNP) | VAF 4/90 reads (4%) | catalogued as rs962826960; called by muse, mutect2
- MCM2 | c.*210G>A | 3'UTR (SNP) | VAF 41/112 reads (37%) | catalogued as rs1197937893; called by muse, mutect2, varscan2
- MCPH1 | c.*430G>A | 3'UTR (SNP) | VAF 5/14 reads (36%) | called by muse, mutect2, varscan2
- NEBL | c.*735G>A | 3'UTR (SNP) | VAF 19/40 reads (48%) | called by muse, mutect2, varscan2
- NRXN1 | c.820+10C>T | Intron (SNP) | VAF 67/113 reads (59%) | catalogued as rs778926130; called by muse, mutect2, varscan2
- PAQR6 | c.*802G>A | 3'UTR (SNP) | VAF 20/89 reads (22%) | called by muse, mutect2, varscan2
- PPP2R5A | c.-203A>G | 5'UTR (SNP) | VAF 79/106 reads (75%) | catalogued as rs1312667001; called by muse, mutect2, varscan2
- PRPF40A | c.*2242A>G | 3'UTR (SNP) | VAF 23/52 reads (44%) | catalogued as rs1055617578; called by muse, mutect2, varscan2
- TRIM15 | c.880+27A>G | Intron (SNP) | VAF 43/120 reads (36%) | catalogued as rs1308998412; called by muse, mutect2, varscan2
- VWC2L | c.*724C>T | 3'UTR (SNP) | VAF 16/87 reads (18%) | catalogued as rs575706457; called by muse, mutect2, varscan2
- ZFP36L1 | c.-1664A>T | 5'UTR (SNP) | VAF 24/58 reads (41%) | called by muse, mutect2, varscan2
